Somatic mutation profile of tumor specimen TCGA-34-8455-01A (aliquot TCGA-34-8455-01A-11D-2323-08) from TCGA case TCGA-34-8455, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 67.4 years (24,624 days).
Specimen TCGA-34-8455-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95bff15c-0395-47f0-8bf5-e5bf84b32e69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-8455-10A (Blood Derived Normal), aliquot TCGA-34-8455-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89d533b2-34c5-49db-8895-a478a65a9f59

The open-access MAF lists 541 somatic variants for this specimen: 421 protein-altering or splice-affecting, 110 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 354, Silent 110, Nonsense Mutation 32, Splice Site 15, Frame Shift Del 13, Splice Region 4, RNA 4, Frame Shift Ins 3, Intron 2, 3'UTR 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.747G>C p.R249S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AASDH | c.3266G>T p.C1089F | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1401813809, COSV52703754, COSV52709920; called by muse, mutect2, varscan2
- ABCG8 | c.373G>T p.G125C | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99700208; called by muse, mutect2, varscan2
- AC011455.2 | c.1357G>T p.G453C | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99671526; called by muse, mutect2, varscan2
- ACVR1C | c.1472G>T p.C491F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs761533712, COSV99695004; called by muse, mutect2, varscan2
- ADA2 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs140149634; called by muse, mutect2, varscan2
- ADAM2 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773542905, COSV55864214, COSV99697801; called by muse, mutect2, varscan2
- ADCY10 | c.3727C>A p.L1243M | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.087); catalogued as COSV100897051; called by muse, mutect2, varscan2
- ADGRB2 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs776049893, COSV99926835; called by muse, mutect2, varscan2
- ADIG | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99485714; called by muse, mutect2, varscan2
- ADORA1 | c.396G>T p.W132C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99704704; called by muse, mutect2, varscan2
- AFDN | c.1519G>T p.A507S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100653470, COSV60047823; called by muse, mutect2, varscan2
- AFF2 | c.2524A>T p.T842S | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99665914; called by muse, mutect2, varscan2
- AKAP9 | c.7105A>G p.R2369G (on ENST00000359028; = p.R2345G on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV100662968; called by muse, mutect2, varscan2
- AMBRA1 | c.675G>T p.Q225H | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV100095191; called by muse, mutect2, varscan2
- ANKRD17 | c.3435G>T p.Q1145H | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.877); catalogued as COSV100429874, COSV58229033; called by muse, mutect2, varscan2
- ANKRD55 | c.1009C>A p.Q337K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.01); catalogued as COSV100591587; called by muse, mutect2, varscan2
- ANO3 | c.374G>C p.R125P | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.137); catalogued as rs996483030, COSV99885271; called by muse, mutect2, varscan2
- ANO4 | c.1778C>A p.T593N (on ENST00000392977 / NM_001286615.2; = p.T558N on NM_178826.4) | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100153641; called by muse, varscan2
- APAF1 | c.3040G>A p.D1014N (on ENST00000551964 / NM_181861.2; = p.D960N on NM_001160.3) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as rs745664662, COSV59662355; called by muse, mutect2, varscan2
- APBB2 | c.602T>A p.I201N | Missense Mutation (SNP) | VAF 141/366 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as rs1196785212, COSV99923975; called by muse, mutect2, varscan2
- ARHGAP33 | c.3116G>T p.G1039V | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as COSV99139795; called by muse, mutect2, varscan2
- ARID2 | c.3018G>A p.M1006I | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.275); catalogued as COSV100536921; called by muse, mutect2, varscan2
- ARMC6 | c.1286G>T p.G429V (on ENST00000392336; = p.G404V on NM_033415.4) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV99523151; called by muse, mutect2, varscan2
- ASCC3 | c.772A>T p.I258F | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV100226231; called by muse, mutect2, varscan2
- ASTN1 | c.1033C>G p.P345A | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.987); catalogued as rs1420457525, COSV56066371, COSV99922846; called by muse, mutect2, varscan2
- ATP11B | c.2781A>G p.I927M | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV100018050; called by muse, mutect2, varscan2
- ATP13A4 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 38/164 reads (23%) | catalogued as COSV99795175; called by muse, mutect2, varscan2
- ATP1A2 | c.2345C>A p.P782H | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100768118; called by muse, mutect2, varscan2
- ATP1A4 | c.1530C>A p.H510Q | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs761721153, COSV100927632; called by muse, mutect2, varscan2
- ATRNL1 | c.1244C>A p.S415* | Nonsense Mutation (SNP) | VAF 59/133 reads (44%) | catalogued as COSV100746824; called by muse, mutect2, varscan2
- BCAM | c.267G>T p.Q89H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99538946; called by muse, mutect2, varscan2
- BCKDHB | c.929G>T p.W310L | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100243346, COSV100244012; called by muse, mutect2, varscan2
- BIN1 | c.318C>T p.N106= | Splice Region (SNP) | VAF 21/61 reads (34%) | catalogued as COSV99388462; called by muse, mutect2, varscan2
- BIRC6 | c.4160A>G p.D1387G | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as rs770910769, COSV101428724; called by muse, mutect2, varscan2
- BPIFB2 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV99401630; called by muse, mutect2, varscan2
- C12orf40 | c.1160A>T p.N387I | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as COSV100210663; called by muse, mutect2, varscan2
- C20orf85 | c.159G>T p.K53N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV100959493; called by muse, mutect2, varscan2
- C4BPB | c.746C>A p.A249E | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.154); catalogued as COSV99700157; called by muse, mutect2, varscan2
- C6orf118 | c.933C>A p.Y311* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV100025018; called by muse, mutect2, varscan2
- CAMTA1 | c.3938C>T p.S1313F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.359); catalogued as COSV100352198; called by muse, mutect2, varscan2
- CAVIN2 | c.846A>G p.I282M | Missense Mutation (SNP) | VAF 77/265 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100414328; called by muse, mutect2, varscan2
- CCDC136 | c.3301G>T p.A1101S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99923100; called by muse, mutect2, varscan2
- CCN2 | c.814G>T p.G272C | Missense Mutation (SNP) | VAF 149/472 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63466550; called by muse, mutect2, varscan2
- CD1A | c.605-1G>C p.X202_splice | Splice Site (SNP) | VAF 35/97 reads (36%) | catalogued as COSV99192583; called by muse, mutect2, varscan2
- CD209 | c.989T>G p.V330G | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99214349; called by muse, mutect2, varscan2
- CDCA2 | c.1060G>C p.D354H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV100399105; called by muse, mutect2, varscan2
- CDH13 | c.941C>A p.P314H | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99230213; called by muse, mutect2, varscan2
- CEBPE | c.439C>A p.H147N | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as COSV99247691; called by muse, mutect2, varscan2
- CERS1 | c.1027G>A p.G343S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53195964; called by muse, varscan2
- CFAP100 | c.578T>A p.L193Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100729392; called by muse, mutect2, varscan2
- CFHR2 | c.448G>T p.G150W | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100804388; called by muse, mutect2, varscan2
- CFHR2 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV66381253, COSV66382351; called by muse, mutect2, varscan2
- CHD7 | c.6670G>A p.G2224S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs758745100, COSV101418294, COSV101418401; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHM | c.1846C>T p.L616F | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV63304736; called by muse, mutect2, varscan2
- CHST8 | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV99381558; called by muse, mutect2, varscan2
- CIT | c.2164G>T p.E722* | Nonsense Mutation (SNP) | VAF 45/160 reads (28%) | catalogued as COSV99950762; called by muse, mutect2, varscan2
- CLIC5 | c.817G>T p.A273S (on ENST00000185206 / NM_001370649.1; = p.A114S on NM_016929.5) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99485277; called by muse, mutect2, varscan2
- CNTN1 | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 79/227 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100751847; called by muse, mutect2, varscan2
- CNTN5 | c.2455C>A p.R819S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.999); catalogued as COSV54287050, COSV99680662; called by muse, mutect2, varscan2
- COL22A1 | c.431A>T p.Q144L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV100280493; called by muse, mutect2, varscan2
- COL4A1 | c.3743-2A>C p.X1248_splice | Splice Site (SNP) | VAF 43/127 reads (34%) | catalogued as COSV101011502; called by muse, mutect2, varscan2
- COL4A2 | c.1804G>C p.D602H | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100847464, COSV64628126; called by muse, mutect2, varscan2
- COL4A2 | c.4444C>A p.P1482T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100847465; called by muse, mutect2, varscan2
- COL4A4 | c.3431C>T p.P1144L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV100307574; called by muse, mutect2, varscan2
- COL6A3 | c.6410G>T p.G2137V | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99800876; called by muse, mutect2, varscan2
- COL6A3 | c.6409G>C p.G2137R | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99800880; called by muse, mutect2, varscan2
- COL6A3 | c.3022C>A p.Q1008K | Missense Mutation (SNP) | VAF 108/321 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.138); catalogued as COSV99800882; called by muse, mutect2, varscan2
- CPA3 | c.922C>A p.Q308K | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265404514, COSV99936428; called by muse, mutect2, varscan2
- CPNE4 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101456800; called by muse, mutect2, varscan2
- CRB1 | c.2005G>T p.G669C | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100958060; called by muse, mutect2, varscan2
- CSGALNACT2 | c.142G>T p.V48F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV100989843; called by muse, mutect2, varscan2
- CSMD2 | c.1937G>A p.G646D | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99594534; called by muse, mutect2, varscan2
- CSPG4 | c.4826C>A p.S1609Y | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100414112; called by muse, mutect2, varscan2
- CTNNA2 | c.1797C>A p.N599K | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs371544995, COSV100561885; called by muse, mutect2, varscan2
- CUBN | c.3937A>T p.T1313S | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.19); catalogued as COSV100913419, COSV64719335; called by muse, mutect2, varscan2
- CWH43 | c.441G>T p.W147C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99893969; called by muse, mutect2, varscan2
- DCHS1 | c.3110C>A p.A1037E | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.996); catalogued as COSV100202511; called by muse, mutect2, varscan2
- DCSTAMP | c.962T>G p.I321S | Missense Mutation (SNP) | VAF 106/314 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99886904; called by muse, mutect2, varscan2
- DCSTAMP | c.1400C>A p.A467E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99886903, COSV99886906; called by muse, mutect2
- DDX60 | c.2374A>G p.T792A | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101190627; called by muse, mutect2, varscan2
- DDX60 | c.343A>G p.T115A | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV101190628; called by muse, mutect2, varscan2
- DEFB126 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 38/116 reads (33%) | catalogued as COSV101215702; called by muse, mutect2, varscan2
- DLG4 | c.1318G>T p.D440Y (on ENST00000399506 / NM_001321075.3; = p.D483Y on NM_001365.4) | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100263807; called by muse, mutect2, varscan2
- DMBX1 | c.1113C>A p.H371Q | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100760892, COSV63601955; called by muse, mutect2, varscan2
- DNAH7 | c.6094G>A p.G2032S | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100417159; called by muse, mutect2, varscan2
- DNHD1 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV99600878; called by muse, mutect2, varscan2
- DOCK2 | c.1254G>C p.M418I | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV56962687, COSV99914907; called by muse, mutect2, varscan2
- DOCK2 | c.4555G>A p.D1519N | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56959784; called by muse, mutect2, varscan2
- DOCK8 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as COSV101210343; called by muse, mutect2, varscan2
- DPF3 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100818671, COSV63501646; called by muse, mutect2, varscan2
- DPH1 | c.1279A>T p.S427C | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as COSV99559636; called by muse, mutect2, varscan2
- DSCAML1 | c.6334C>A p.L2112M (on ENST00000321322; = p.L2052M on NM_020693.4) | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100356994; called by muse, mutect2, varscan2
- DUSP21 | c.475A>C p.K159Q | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT tolerated (0.37); PolyPhen benign (0.101); catalogued as COSV100173661; called by muse, mutect2, varscan2
- DYRK1B | c.763A>T p.I255F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100546719, COSV59914592; called by muse, mutect2, varscan2
- EIF4G1 | c.4300G>T p.G1434C (on ENST00000346169 / NM_198241.3; = p.G1239C on NM_004953.5) | Missense Mutation (SNP) | VAF 75/300 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs777194473, COSV100072244; called by muse, mutect2, varscan2
- ELAVL2 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780367763, COSV56370550, COSV99807039; called by muse, mutect2, varscan2
- ENAM | c.1739C>A p.P580Q | Missense Mutation (SNP) | VAF 82/228 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV101253300; called by muse, mutect2, varscan2
- ENPP1 | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100719632; called by muse, mutect2, varscan2
- EPHA3 | c.1151C>G p.P384R | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100346195, COSV100348189; called by muse, mutect2, varscan2
- EPHA3 | c.2107G>T p.E703* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100348193, COSV60694522; called by muse, mutect2, varscan2
- EVC2 | c.518T>A p.L173Q | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.459); catalogued as COSV100186744, COSV60401627; called by muse, mutect2, varscan2
- F13B | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100803192; called by muse, mutect2, varscan2
- FAM120B | c.2333G>T p.R778L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99379892; called by muse, mutect2, varscan2
- FAM237A | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); catalogued as COSV71513286; called by mutect2, varscan2
- FAM47B | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 63/82 reads (77%) | SIFT tolerated (0.53); PolyPhen benign (0.419); catalogued as COSV100264157, COSV100264570, COSV61452717; called by muse, mutect2, varscan2
- FAN1 | c.873A>T p.E291D | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100756069; called by muse, mutect2, varscan2
- FAT3 | c.10224G>T p.R3408= | Splice Region (SNP) | VAF 10/53 reads (19%) | catalogued as COSV99964792; called by muse, mutect2, varscan2
- FAT3 | c.11689G>T p.D3897Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99969293; called by muse, mutect2
- FBN3 | c.6969G>T p.E2323D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.186); catalogued as COSV99561707; called by muse, mutect2, varscan2
- FBXW11 | c.556G>T p.G186W | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV99441357; called by muse, mutect2, varscan2
- FCER1A | c.283C>A p.H95N | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100929302; called by muse, mutect2, varscan2
- FGB | c.1379G>T p.G460V | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100122546; called by muse, mutect2, varscan2
- FGF6 | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); catalogued as COSV99960393; called by muse, mutect2, varscan2
- FLG | c.1869G>T p.Q623H | Missense Mutation (SNP) | VAF 120/486 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1342792032, COSV100912044; called by muse, mutect2, varscan2
- FLG | c.1096C>A p.R366S | Missense Mutation (SNP) | VAF 184/620 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as rs371936330, COSV100912045, COSV64250428; called by muse, mutect2, varscan2
- FNDC7 | c.1121G>T p.C374F | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99601642; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as COSV100437764, COSV58547926; called by muse, mutect2, varscan2
- FPR2 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100389417; called by muse, mutect2, varscan2
- FSIP2 | c.18476A>T p.Q6159L | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as COSV100556199; called by muse, mutect2, varscan2
- GADL1 | c.611T>G p.L204R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99244982; called by muse, mutect2, varscan2
- GGCT | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99139207; called by muse, mutect2, varscan2
- GGCT | c.349G>C p.G117R | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.387); catalogued as COSV99139208; called by muse, mutect2, varscan2
- GGCX | c.696G>C p.L232F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99290158; called by muse, mutect2, varscan2
- GHSR | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV53839553, COSV99577172; called by muse, mutect2, varscan2
- GLT8D2 | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100674183; called by muse, mutect2, varscan2
- GPAT2 | c.47G>T p.S16I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as COSV100853348; called by muse, mutect2, varscan2
- GPR75 | c.1576G>T p.E526* | Nonsense Mutation (SNP) | VAF 48/128 reads (38%) | catalogued as COSV100766367; called by muse, mutect2, varscan2
- GRAMD1A | c.1135G>T p.G379C | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100526398; called by muse, mutect2, varscan2
- GRAMD1B | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV100455161; called by muse, mutect2
- GRIA3 | c.2445G>C p.K815N | Missense Mutation (SNP) | VAF 71/123 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99991518; called by muse, mutect2, varscan2
- GRID2 | c.1696G>T p.D566Y | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56202556, COSV99945884; called by muse, mutect2, varscan2
- GRIN2B | c.3805C>A p.P1269T | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV101663172; called by muse, mutect2, varscan2
- GRIN3A | c.1105G>T p.G369C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100701759; called by muse, mutect2, varscan2
- H4C3 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100619644; called by muse, mutect2
- HCN1 | c.2537C>G p.S846W | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100301983, COSV57520811; called by muse, mutect2, varscan2
- HCN1 | c.1400G>C p.R467P | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as rs773990933, COSV100302013, COSV57508684; called by muse, mutect2, varscan2
- HEMGN | c.1012C>A p.P338T | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as COSV99412500; called by muse, mutect2, varscan2
- HEPHL1 | c.148G>C p.G50R | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100244303; called by muse, mutect2, varscan2
- HLA-DRB1 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs531360990, COSV63513290; called by muse, mutect2, varscan2
- HLX | c.1342A>G p.S448G | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV100854615; called by muse, mutect2, varscan2
- HSD17B4 | c.775G>A p.G259S (on ENST00000414835 / NM_001199291.3; = p.G234S on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV99820121; called by muse, mutect2, varscan2
- HTR4 | c.1113G>T p.Q371H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.025); catalogued as COSV100089494; called by muse, mutect2, varscan2
- HYDIN | c.2083G>T p.V695L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV55486950; called by muse, mutect2, varscan2
- IDO2 | c.232C>T p.R78W (on ENST00000389060; = p.R91W on NM_194294.2) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs377075058, COSV58424136; called by muse, mutect2
- IDO2 | c.233G>T p.R78L (on ENST00000389060; = p.R91L on NM_194294.2) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100584946; called by muse, mutect2
- IFNA4 | c.167G>T p.R56I | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV101427082; called by muse, varscan2
- IGKV1-27 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs754739659; called by muse, mutect2, varscan2
- IMPG2 | c.3116T>A p.F1039Y | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1197777965, COSV99516333; called by muse, mutect2, varscan2
- INTS8 | c.2223A>T p.L741F | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as COSV100569424; called by muse, mutect2, varscan2
- ITGAM | c.3331G>T p.V1111L (on ENST00000648685 / NM_001145808.2; = p.V1110L on NM_000632.4) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.906); catalogued as COSV99793050; called by muse, mutect2, varscan2
- ITIH1 | c.245C>A p.A82D | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99835590; called by muse, mutect2, varscan2
- ITM2A | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 26/40 reads (65%) | catalogued as COSV100964486, COSV64810604; called by muse, mutect2, varscan2
- KALRN | c.7550G>A p.S2517N (on ENST00000360013 / NM_001024660.4; = p.S820N on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.953); catalogued as COSV99362803; called by muse, mutect2, varscan2
- KATNIP | c.4229G>T p.W1410L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99851860; called by muse, mutect2, varscan2
- KCNQ5 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.773); catalogued as COSV100572946; called by muse, mutect2, varscan2
- KCTD18 | c.496A>G p.K166E | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs201517493, COSV100728946; called by muse, mutect2, varscan2
- KIF14 | c.2520A>T p.L840F | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100951036; called by muse, mutect2, varscan2
- KIF26B | c.706G>T p.V236L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as rs369084969, COSV101314151; called by muse, varscan2
- KIF5B | c.2726A>G p.K909R | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as COSV100192316; called by muse, mutect2, varscan2
- KIFC2 | c.2267A>T p.K756M | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as COSV100023976; called by muse, mutect2
- KRT27 | c.1281G>T p.E427D | Missense Mutation (SNP) | VAF 59/86 reads (69%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.485); catalogued as COSV100053354; called by muse, mutect2, varscan2
- KRT78 | c.1475C>G p.S492C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100398539; called by muse, mutect2, varscan2
- KRTAP1-3 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100727496; called by muse, mutect2, varscan2
- KRTAP21-1 | c.217A>T p.R73* | Nonsense Mutation (SNP) | VAF 60/137 reads (44%) | catalogued as COSV100624959; called by muse, mutect2, varscan2
- LAMA2 | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV101370782; called by muse, mutect2, varscan2
- LAMB4 | c.2245G>C p.G749R | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.075); catalogued as COSV99225397; called by muse, mutect2, varscan2
- LCORL | c.697G>C p.D233H | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs780294822, COSV100482144; called by muse, mutect2, varscan2
- LEF1 | c.832G>C p.D278H | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.289); catalogued as COSV99489992; called by muse, mutect2, varscan2
- LILRA4 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99393350; called by muse, mutect2, varscan2
- LRP1B | c.9694G>A p.G3232R | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV101260100; called by muse, mutect2, varscan2
- LRRC6 | c.395G>T p.R132M | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51544476, COSV99138509; called by muse, mutect2, varscan2
- LRRK1 | c.1754G>T p.R585L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV52621830; called by muse, mutect2, varscan2
- LRRK2 | c.3546G>C p.Q1182H | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100111021; called by muse, mutect2, varscan2
- LRRN2 | c.998A>T p.H333L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.415); catalogued as COSV100912937; called by muse, mutect2, varscan2
- MADD | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs532391313, COSV100211906; called by muse, mutect2, varscan2
- MAP1B | c.3766A>T p.S1256C | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99702882; called by muse, mutect2, varscan2
- MARCO | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV100503786, COSV59053779; called by muse, mutect2, varscan2
- MED23 | c.3434G>C p.W1145S | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100645371; called by muse, mutect2, varscan2
- MGAM | c.3701G>T p.G1234V | Missense Mutation (SNP) | VAF 109/323 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101527723; called by muse, mutect2, varscan2
- MGRN1 | c.115A>T p.M39L | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV99274761; called by muse, mutect2, varscan2
- MOB1A | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101247335; called by muse, mutect2, varscan2
- MRPS28 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99399079; called by muse, mutect2, varscan2
- MS4A12 | c.625T>A p.F209I | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.675); catalogued as COSV99189636; called by muse, mutect2, varscan2
- MSH4 | c.2449G>T p.V817L | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV54201241, COSV99592421; called by muse, mutect2, varscan2
- MUC15 | c.459G>T p.L153F | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV99846647; called by muse, mutect2, varscan2
- MUC16 | c.28564C>G p.H9522D | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.044); catalogued as COSV101201308; called by muse, mutect2, varscan2
- MUC16 | c.18575T>A p.V6192E | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.065); catalogued as COSV101201309; called by muse, mutect2, varscan2
- MYO1F | c.3229G>A p.G1077S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100597021; called by muse, mutect2, varscan2
- MYO7B | c.753C>G p.N251K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101268366; called by muse, varscan2
- N4BP2 | c.2389A>G p.I797V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV99789202; called by muse, mutect2, varscan2
- NAA16 | c.1950A>G p.V650= | Splice Region (SNP) | VAF 17/32 reads (53%) | catalogued as rs772573242, COSV65130582; called by muse, mutect2, varscan2
- NAALAD2 | c.803C>A p.T268N | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV100428752; called by muse, mutect2, varscan2
- NAV3 | c.740+1G>T p.X247_splice | Splice Site (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99894872; called by muse, mutect2
- NAV3 | c.7082G>A p.S2361N (on ENST00000397909 / NM_001024383.2; = p.S2339N on NM_014903.6) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs765338002, COSV99894876; called by muse, mutect2, varscan2
- NCOR1 | c.2083G>T p.D695Y | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99251797; called by muse, mutect2, varscan2
- NELL1 | c.2378G>T p.C793F | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100124470; called by muse, mutect2, varscan2
- NELL2 | c.752C>A p.T251K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV61572074; called by muse, mutect2, varscan2
- NEXMIF | c.2122G>T p.E708* | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | catalogued as COSV50026376, COSV50037237; called by muse, mutect2, varscan2
- NF1 | c.1392+1G>T p.X464_splice | Splice Site (SNP) | VAF 26/62 reads (42%) | catalogued as CS041541, CS1311506, COSV62202943, COSV62227804; called by muse, mutect2, varscan2
- NFYA | c.887G>T p.R296M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100399812; called by muse, mutect2, varscan2
- NIPBL | c.2813A>G p.K938R | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.3); catalogued as rs1398503267, COSV99242350; called by muse, mutect2, varscan2
- NKX2-2 | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV101010618; called by muse, mutect2, varscan2
- NLRP5 | c.399G>T p.M133I | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV101173858, COSV66762248; called by muse, mutect2, varscan2
- NOS1 | c.3121T>A p.F1041I | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV100501301; called by muse, mutect2, varscan2
- NOX5 | c.759C>A p.F253L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV99534639; called by muse, mutect2
- NPSR1 | c.680G>T p.S227I | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100707073, COSV62207350; called by muse, mutect2, varscan2
- NPTX1 | c.1205T>A p.L402Q | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100151166; called by muse, mutect2, varscan2
- NPY1R | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV56714820, COSV99649040; called by muse, mutect2, varscan2
- NTSR1 | c.133C>A p.R45S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100980707; called by muse, mutect2, varscan2
- NUDCD3 | c.976-2A>G p.X326_splice | Splice Site (SNP) | VAF 21/46 reads (46%) | catalogued as COSV100622046; called by muse, mutect2, varscan2
- NUP205 | c.878A>G p.D293G | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.501); catalogued as rs755605159, COSV99607480; called by muse, mutect2, varscan2
- OCM | c.119C>A p.S40* | Nonsense Mutation (SNP) | VAF 30/195 reads (15%) | catalogued as COSV99631513; called by muse, mutect2, varscan2
- OLFML2A | c.353A>T p.K118M | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100053785; called by muse, mutect2, varscan2
- OMP | c.372G>T p.E124D | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99582514; called by muse, mutect2, varscan2
- OR10P1 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs777143992, COSV100548210; called by muse, mutect2, varscan2
- OR11L1 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100869478, COSV63315144; called by muse, mutect2, varscan2
- OR14C36 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100507632; called by muse, mutect2, varscan2
- OR1L3 | c.91T>A p.F31I | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV100506301; called by muse, mutect2, varscan2
- OR2A12 | c.683A>T p.Q228L | Missense Mutation (SNP) | VAF 89/233 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV101283200; called by muse, mutect2, varscan2
- OR2L2 | c.140T>G p.L47R | Missense Mutation (SNP) | VAF 84/323 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1227847151, COSV100824305; called by muse, mutect2, varscan2
- OR2M4 | c.910G>T p.V304L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV100141482; called by muse, mutect2
- OR2T11 | c.713G>C p.C238S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100424934; called by muse, mutect2, varscan2
- OR2T12 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV100527952, COSV100527963; called by muse, mutect2, varscan2
- OR2T27 | c.133A>G p.K45E | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs777931052, COSV100788369; called by mutect2, varscan2
- OR2W1 | c.6C>A p.D2E | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV101013938; called by muse, mutect2, varscan2
- OR4K13 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100237872; called by muse, mutect2, varscan2
- OR4M1 | c.735C>A p.H245Q | Missense Mutation (SNP) | VAF 40/362 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100271487, COSV60063874; called by muse, mutect2, varscan2
- OR4Q3 | c.360G>C p.E120D | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100057334; called by muse, mutect2, varscan2
- OR51A2 | c.341C>A p.S114Y | Missense Mutation (SNP) | VAF 86/206 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV100985088; called by muse, mutect2, varscan2
- OR5AN1 | c.225C>G p.I75M | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.282); catalogued as rs766425545, COSV100004448; called by muse, mutect2, varscan2
- OR5B17 | c.601T>C p.S201P | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV100641954; called by muse, mutect2, varscan2
- OR5B3 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as COSV100512061; called by muse, mutect2, varscan2
- OR5D18 | c.688C>A p.R230S | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs143615376, COSV100450494, COSV100450859; called by muse, mutect2, varscan2
- OR8B12 | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV100172924, COSV60911567; called by muse, mutect2, varscan2
- OR8B2 | c.368A>C p.Y123S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100899494; called by muse, mutect2, varscan2
- OR8G5 | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs764069405, COSV58381498; called by muse, mutect2, varscan2
- OR8H2 | c.655G>T p.V219L | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0.019); catalogued as COSV57943776; called by muse, mutect2, varscan2
- ORC5 | c.358G>C p.V120L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV52399523, COSV99857307; called by muse, mutect2
- OTUD6A | c.78C>G p.I26M | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100611066; called by muse, mutect2, varscan2
- P4HA2 | c.345C>G p.N115K | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99387388; called by muse, mutect2, varscan2
- PAPOLB | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.661); catalogued as COSV101271606; called by muse, varscan2
- PC | c.1132G>T p.V378F | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV100852081, COSV100852334; called by muse, mutect2, varscan2
- PCDH10 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 51/249 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs1210216695, COSV99992585, COSV99994753; called by muse, mutect2, varscan2
- PCDH10 | c.2480C>A p.P827H | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99994371; called by muse, mutect2, varscan2
- PCDH11X | c.1281G>T p.E427D | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100014619; called by muse, mutect2, varscan2
- PCDH15 | c.5361C>A p.N1787K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0.01); catalogued as COSV100905481; called by muse, mutect2, varscan2
- PCDH15 | c.1697C>A p.T566N | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV100226614; called by muse, mutect2, varscan2
- PCDH15 | c.1072C>A p.H358N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.391); catalogued as COSV100226616; called by muse, mutect2, varscan2
- PCDH17 | c.3307G>T p.V1103L | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.058); catalogued as COSV100931946; called by muse, mutect2, varscan2
- PCDHGB4 | c.2337C>A p.C779* | Nonsense Mutation (SNP) | VAF 95/191 reads (50%) | catalogued as COSV99531474, COSV99545703; called by muse, mutect2, varscan2
- PDE3B | c.1413A>T p.S471= | Splice Region (SNP) | VAF 20/65 reads (31%) | catalogued as COSV99963161; called by muse, mutect2, varscan2
- PDZD2 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99224641; called by muse, mutect2, varscan2
- PES1 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100073303; called by muse, mutect2, varscan2
- PGM2 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV101126633; called by muse, mutect2, varscan2
- PHKA1 | c.773G>T p.S258I | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100263833; called by muse, mutect2, varscan2
- PIK3C2A | c.3681+1G>T p.X1227_splice | Splice Site (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99791145; called by muse, mutect2, varscan2
- PITHD1 | c.202G>T p.V68F | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1451918214, COSV99862219; called by muse, mutect2, varscan2
- PNLIPRP2 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100077949; called by muse, mutect2, varscan2
- POTEE | c.84C>G p.C28W | Missense Mutation (SNP) | VAF 104/313 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.675); catalogued as COSV100386885, COSV100388818; called by muse, mutect2, varscan2
- POU2F2 | c.1103G>T p.G368V (on ENST00000526816 / NM_001207025.3; = p.G352V on NM_002698.5) | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.997); catalogued as COSV100657507; called by muse, mutect2, varscan2
- POU4F1 | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1370740493, COSV65885047; called by muse, mutect2
- PPP1R13L | c.764T>A p.L255Q | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100714869; called by muse, mutect2, varscan2
- PPP3CA | c.388G>T p.V130L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs1385558748, COSV100548001, COSV59929574; called by muse, mutect2, varscan2
- PRAME | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs766765036, COSV101287220; called by muse, mutect2, varscan2
- PRDM9 | c.1376G>C p.R459T | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.083); catalogued as COSV99691117; called by muse, mutect2, varscan2
- PRG4 | c.2342C>T p.T781I | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV100798307; called by muse, mutect2, varscan2
- PRKCB | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as COSV100335207; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1757A>G p.Y586C (on ENST00000352766; = p.Y507C on NM_181334.5) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.753); catalogued as rs562032283, COSV100424619; called by muse, mutect2, varscan2
- PTK2 | c.789+1G>T p.X263_splice | Splice Site (SNP) | VAF 35/151 reads (23%) | catalogued as COSV100571087; called by muse, mutect2, varscan2
- PTN | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100781006; called by muse, mutect2, varscan2
- PTPN14 | c.511-2A>T p.X171_splice | Splice Site (SNP) | VAF 48/145 reads (33%) | catalogued as COSV100872902; called by muse, mutect2, varscan2
- PTPRB | c.1511G>T p.R504I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.262); catalogued as COSV99718728; called by muse, mutect2, varscan2
- PYGM | c.2399G>A p.R800Q | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs1476157353, COSV99377545; called by muse, mutect2, varscan2
- QSOX1 | c.465G>T p.E155D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100852944; called by muse, mutect2, varscan2
- RAG1 | c.1465A>T p.R489W | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100201117; called by muse, mutect2, varscan2
- RAPGEF2 | c.2109G>C p.Q703H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.179); catalogued as COSV100031572; called by muse, mutect2, varscan2
- RASSF9 | c.310G>T p.G104* | Nonsense Mutation (SNP) | VAF 46/169 reads (27%) | catalogued as COSV100771549, COSV63435941; called by muse, mutect2, varscan2
- RBM45 | c.424-1G>A p.X142_splice | Splice Site (SNP) | VAF 11/49 reads (22%) | catalogued as rs752687294, COSV99617937; called by muse, mutect2, varscan2
- RCCD1 | c.820G>T p.G274C | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV101263242; called by muse, mutect2, varscan2
- RFLNB | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV100225112; called by muse, mutect2, varscan2
- RIPK4 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | catalogued as COSV100205328; called by muse, mutect2, varscan2
- RNASEL | c.1620G>T p.E540D | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as COSV100842639; called by muse, mutect2, varscan2
- ROBO1 | c.779A>T p.E260V | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101459210; called by muse, mutect2, varscan2
- ROBO4 | c.2674C>A p.L892I | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV100127825; called by muse, mutect2, varscan2
- ROR2 | c.1998C>A p.Y666* | Nonsense Mutation (SNP) | VAF 20/30 reads (67%) | catalogued as COSV100996078, COSV65224658; called by muse, mutect2, varscan2
- RPS6KA1 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100943292; called by muse, mutect2, varscan2
- RXYLT1 | c.428+1G>T p.X143_splice | Splice Site (SNP) | VAF 12/63 reads (19%) | catalogued as COSV99706804, COSV99707078; called by muse, mutect2, varscan2
- RYR3 | c.1392C>A p.N464K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV101214187; called by muse, mutect2, varscan2
- SAMD11 | c.577C>G p.R193G | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV100498160; called by muse, mutect2, varscan2
- SASH1 | c.2768C>G p.S923* | Nonsense Mutation (SNP) | VAF 24/107 reads (22%) | catalogued as COSV100821405; called by muse, mutect2, varscan2
- SCN2A | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as COSV99333176; called by muse, mutect2, varscan2
- SCN5A | c.4453A>T p.I1485F (on ENST00000333535 / NM_198056.3; = p.I1484F on NM_000335.5) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as CM159536, COSV100350265; called by muse, mutect2, varscan2
- SCP2 | c.794G>C p.S265T | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV101027197; called by muse, mutect2, varscan2
- SCP2D1 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99602184; called by muse, mutect2, varscan2
- SCTR | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99191711; called by muse, mutect2, varscan2
- SCTR | c.784G>T p.G262* | Nonsense Mutation (SNP) | VAF 21/85 reads (25%) | catalogued as COSV50027882, COSV99191616; called by muse, mutect2, varscan2
- SDC4 | c.200-2A>G p.X67_splice | Splice Site (SNP) | VAF 27/107 reads (25%) | catalogued as COSV101023558; called by muse, mutect2, varscan2
- SDHA | c.1658A>T p.D553V | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99372126; called by muse, mutect2
- SEC23A | c.1240A>T p.I414L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100305801; called by muse, mutect2, varscan2
- SELPLG | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs774445083, COSV99947634; called by muse, mutect2, varscan2
- SEMA5A | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as COSV101228688; called by muse, mutect2, varscan2
- SEMA5B | c.1451C>A p.T484K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.559); catalogued as COSV99533018; called by muse, mutect2, varscan2
- SERPINB3 | c.1099C>A p.H367N | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52191331, COSV99380160; called by muse, mutect2, varscan2
- SF3B1 | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100135604; called by muse, mutect2, varscan2
- SH3D19 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100455897; called by muse, mutect2, varscan2
- SH3YL1 | c.411G>C p.L137F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV100642240; called by muse, mutect2, varscan2
- SHANK1 | c.6476T>A p.L2159Q | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV99521877; called by muse, mutect2, varscan2
- SI | c.4784C>A p.T1595K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780262949, COSV52294044; called by muse, mutect2, varscan2
- SIGLEC1 | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99170476; called by mutect2, varscan2
- SIGLEC8 | c.255C>G p.D85E | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as rs146821067; called by muse, mutect2, varscan2
- SLC22A12 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV100327846; called by muse, mutect2, varscan2
- SLC22A12 | c.1460G>T p.R487L | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV100327850; called by muse, mutect2, varscan2
- SLC30A10 | c.1426G>T p.D476Y | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as COSV100751436; called by muse, mutect2, varscan2
- SLC35G3 | c.520G>T p.G174* | Nonsense Mutation (SNP) | VAF 109/247 reads (44%) | catalogued as COSV52012540; called by muse, mutect2, varscan2
- SLC38A3 | c.933G>T p.K311N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV101309988; called by muse, mutect2, varscan2
- SLC38A3 | c.934G>T p.D312Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV101309989; called by muse, mutect2, varscan2
- SLC4A1 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs760404726, COSV52260579; called by muse, mutect2, varscan2
- SLC6A12 | c.297C>G p.Y99* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100675207; called by muse, mutect2, varscan2
- SLC6A16 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746359821, COSV100242930; called by muse, mutect2, varscan2
- SLC7A13 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); catalogued as COSV99878563, COSV99879162; called by muse, mutect2, varscan2
- SLC7A8 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100328563; called by muse, mutect2, varscan2
- SLCO1B3 | c.1119T>G p.H373Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99682143; called by muse, mutect2, varscan2
- SLCO5A1 | c.352A>T p.R118W | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV99480850; called by muse, mutect2, varscan2
- SLITRK1 | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV101000035, COSV65678040; called by muse, mutect2, varscan2
- SMG5 | c.1481A>G p.D494G | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs943145978, COSV100700903; called by muse, mutect2, varscan2
- SMG8 | c.529G>T p.G177* | Nonsense Mutation (SNP) | VAF 42/64 reads (66%) | catalogued as COSV99959030; called by muse, mutect2, varscan2
- SNCAIP | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs755797209, COSV99750120; called by muse, mutect2, varscan2
- SND1 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.569); catalogued as COSV100691002; called by muse, mutect2, varscan2
- SORCS2 | c.2570C>T p.T857M | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs571439356, COSV100213727; called by muse, mutect2, varscan2
- SORCS3 | c.3167C>G p.A1056G | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100865616; called by muse, mutect2
- SOWAHB | c.1358G>T p.R453L | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1014961729, COSV100530786; called by muse, mutect2, varscan2
- SOX10 | c.1133T>C p.I378T | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV100704188; called by muse, mutect2, varscan2
- SPATA5 | c.1898A>G p.E633G | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV99916277; called by muse, varscan2
- SPATA5 | c.1951G>T p.E651* | Nonsense Mutation (SNP) | VAF 26/130 reads (20%) | catalogued as COSV99916279; called by muse, varscan2
- SRRT | c.1089C>A p.D363E | Missense Mutation (SNP) | VAF 65/382 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.096); catalogued as COSV100730336; called by muse, mutect2, varscan2
- SSH3 | c.105-2A>G p.X35_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100354765; called by muse, mutect2, varscan2
- STON1 | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100562228; called by muse, mutect2, varscan2
- SYNE1 | c.18556A>T p.K6186* (on ENST00000367255 / NM_182961.4; = p.K6115* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 30/176 reads (17%) | catalogued as COSV99576310; called by muse, mutect2, varscan2
- SYNJ2BP | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 83/267 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV99832700; called by muse, mutect2, varscan2
- SYNJ2BP | c.55G>T p.G19W | Missense Mutation (SNP) | VAF 84/268 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99832704; called by muse, mutect2, varscan2
- TAAR6 | c.781G>T p.G261W | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99256879; called by muse, mutect2
- TAS2R40 | c.587T>A p.F196Y | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.471); catalogued as COSV101283023; called by muse, mutect2, varscan2
- TAS2R60 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.582); catalogued as COSV100223661, COSV60331060; called by muse, mutect2, varscan2
- TBC1D25 | c.1825C>T p.Q609* | Nonsense Mutation (SNP) | VAF 51/80 reads (64%) | catalogued as COSV65124041; called by muse, mutect2, varscan2
- TBKBP1 | c.773A>T p.Q258L | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV100659225; called by muse, mutect2, varscan2
- TEC | c.244-1G>T p.X82_splice | Splice Site (SNP) | VAF 18/46 reads (39%) | catalogued as COSV101202677; called by muse, mutect2, varscan2
- TECTA | c.6260G>T p.W2087L | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99881324; called by muse, mutect2, varscan2
- TEKT3 | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100107272; called by muse, mutect2, varscan2
- TENM3 | c.3944C>A p.S1315* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV101305441; called by muse, mutect2, varscan2
- TET1 | c.3768G>T p.K1256N | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV101018822; called by muse, mutect2, varscan2
- TFAP2A | c.890-1G>T p.X297_splice (on ENST00000482890; = p.X289_splice on NM_001032280.3) | Splice Site (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100117151; called by muse, mutect2, varscan2
- TFAP2D | c.427C>A p.H143N | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.775); catalogued as COSV99147286; called by muse, mutect2, varscan2
- THSD7B | c.2389G>T p.V797L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs370936934; called by muse, mutect2, varscan2
- TLL2 | c.1759G>A p.G587R | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs200588066, COSV63570541, COSV63572986; called by muse, mutect2, varscan2
- TLN2 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV100169893; called by muse, mutect2, varscan2
- TMA16 | c.170G>T p.W57L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100667559; called by muse, mutect2, varscan2
- TMA16 | c.171G>T p.W57C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100667560; called by muse, mutect2, varscan2
- TMEM132B | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100170737; called by muse, mutect2, varscan2
- TMEM217 | c.125G>A p.C42Y | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); catalogued as rs576088457, COSV100362678; called by muse, mutect2, varscan2
- TMPRSS11A | c.740C>A p.T247K | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs1490755822, COSV100602820; called by muse, mutect2, varscan2
- TMX3 | c.1313T>A p.V438E | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100218548; called by muse, mutect2, varscan2
- TNR | c.2429C>A p.P810H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99691259; called by muse, mutect2, varscan2
- TOPBP1 | c.687C>A p.Y229* | Nonsense Mutation (SNP) | VAF 20/123 reads (16%) | catalogued as COSV99605770; called by muse, mutect2, varscan2
- TRIM56 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs557322263, COSV100047698; called by muse, mutect2, varscan2
- TRIM6 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV99546785; called by muse, mutect2, varscan2
- TRPA1 | c.3184C>A p.H1062N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV100085048; called by muse, mutect2, varscan2
- TRPM2 | c.1945A>T p.I649F | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as COSV100308949, COSV100309259; called by muse, mutect2, varscan2
- TTK | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748719753, COSV57887662; called by muse, mutect2, varscan2
- TTN | c.9221G>T p.R3074L (on ENST00000591111; = p.R3028L on NM_003319.4) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | PolyPhen possibly damaging (0.668); catalogued as COSV100627063; called by muse, mutect2, varscan2
- TUBA3C | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); catalogued as COSV101262829; called by muse, mutect2, varscan2
- TUBA3C | c.75C>A p.C25* | Nonsense Mutation (SNP) | VAF 55/116 reads (47%) | catalogued as COSV101262830; called by muse, mutect2, varscan2
- UGT2B4 | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100522615; called by muse, mutect2, varscan2
- UNC80 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99778834; called by muse, mutect2, varscan2
- USP7 | c.658G>T p.G220* | Nonsense Mutation (SNP) | VAF 108/237 reads (46%) | catalogued as COSV100784383; called by muse, mutect2, varscan2
- VPS13D | c.3427A>G p.M1143V | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1251141888, COSV99169255; called by muse, mutect2, varscan2
- VPS33A | c.623G>A p.R208K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.06); catalogued as COSV99931541; called by muse, mutect2, varscan2
- VPS35 | c.1105G>C p.V369L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV100140767; called by muse, mutect2, varscan2
- VWA3B | c.2308G>T p.E770* | Nonsense Mutation (SNP) | VAF 22/75 reads (29%) | catalogued as COSV101346139; called by muse, mutect2, varscan2
- WDR17 | c.2097G>C p.W699C | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99708150; called by muse, mutect2, varscan2
- WDR17 | c.3836G>T p.G1279V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99708151; called by muse, mutect2, varscan2
- ZFHX4 | c.1714G>T p.A572S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV51494117; called by muse, mutect2, varscan2
- ZFHX4 | c.2297C>A p.T766N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99266790; called by muse, mutect2, varscan2
- ZFHX4 | c.7075G>T p.V2359L | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV99266792; called by muse, mutect2, varscan2
- ZFP57 | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 108/299 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.225); catalogued as COSV100971950; called by muse, mutect2, varscan2
- ZNF407 | c.5011T>C p.S1671P | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100226927; called by muse, mutect2, varscan2
- ZNF423 | c.78G>C p.W26C (on ENST00000563137 / NM_001379286.1; = p.W18C on NM_015069.4) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV99283507; called by muse, mutect2, varscan2
- ZNF438 | c.1062G>T p.Q354H | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as COSV100062593; called by muse, mutect2, varscan2
- ZNF573 | c.980A>T p.K327I (on ENST00000536220 / NM_001172692.1; = p.K269I on NM_152360.3) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100265806; called by muse, mutect2, varscan2
- ZNF578 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 15/76 reads (20%) | catalogued as COSV101405115; called by muse, mutect2, varscan2
- ZNF630 | c.1161G>A p.M387I | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99332563; called by muse, mutect2, varscan2
- ZNF638 | c.1930C>G p.L644V | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV100039769; called by muse, mutect2, varscan2
- ZNF836 | c.2419G>T p.V807L | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV100441187, COSV59082918; called by muse, mutect2, varscan2
- ZSCAN10 | c.785C>G p.P262R (on ENST00000252463; = p.P317R on NM_032805.3) | Missense Mutation (SNP) | VAF 78/146 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV99374297; called by muse, mutect2, varscan2
- ARPP21 | c.1364del p.G455Afs*37 | Frame Shift Del (DEL) | VAF 30/83 reads (36%) | called by mutect2, pindel, varscan2
- CCL4L2 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 158/738 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- DDX1 | c.228del p.G77Efs*12 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- FLG | c.3542dup p.H1181Qfs*2 | Frame Shift Ins (INS) | VAF 205/787 reads (26%) | called by mutect2, pindel, varscan2
- GPR150 | c.32del p.P11Rfs*18 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | called by mutect2, varscan2
- HECTD1 | c.982_983dup p.L328Ffs*29 | Frame Shift Ins (INS) | VAF 46/154 reads (30%) | called by mutect2, pindel, varscan2
- IGHV3-64 | c.260G>T p.R87I | Missense Mutation (SNP) | VAF 105/354 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- IGKV1-17 | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- IGSF21 | c.934del p.Q312Rfs*36 | Frame Shift Del (DEL) | VAF 38/149 reads (26%) | called by mutect2, pindel, varscan2
- INPP4B | c.256G>T p.G86* | Nonsense Mutation (SNP) | VAF 17/108 reads (16%) | called by muse, mutect2, varscan2
- KCNJ12 | c.1288del p.E430Sfs*46 | Frame Shift Del (DEL) | VAF 3/19 reads (16%) | called by mutect2, pindel
- KDM6A | c.254del p.L85* | Frame Shift Del (DEL) | VAF 16/30 reads (53%) | called by mutect2, pindel, varscan2
- KIR2DL4 | c.1142C>T p.S381F (on ENST00000396284; = p.S307F on NM_001080770.2) | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MBL2 | c.489del p.T164Pfs*35 | Frame Shift Del (DEL) | VAF 27/189 reads (14%) | called by mutect2, pindel, varscan2
- MSRB3 | c.201del p.E68Kfs*45 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- NBPF11 | c.1072A>C p.K358Q | Missense Mutation (SNP) | VAF 121/396 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR2T4 | c.478del p.H160Ifs*9 | Frame Shift Del (DEL) | VAF 59/288 reads (20%) | called by mutect2, varscan2
- OR4A47 | c.642_646del p.S215Wfs*11 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | called by mutect2, pindel, varscan2
- PCDH7 | c.2310G>T p.Q770H | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCLO | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- PTPRO | c.1129del p.V377Wfs*12 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- SLC12A3 | c.2733dup p.E912* (on ENST00000563236 / NM_001126108.2; = p.E921* on NM_000339.3) | Frame Shift Ins (INS) | VAF 36/123 reads (29%) | called by mutect2, pindel, varscan2
- SLC17A4 | c.1005del p.L336Cfs*45 | Frame Shift Del (DEL) | VAF 80/249 reads (32%) | called by mutect2, pindel, varscan2
- SORCS3 | c.623C>A p.S208Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- TCAF1 | c.2327A>T p.E776V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TGM7 | c.1679-3_1694del p.X560_splice | Splice Site (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- TWF2 | c.54del p.K19Rfs*13 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- AC011455.2 | c.1356G>T p.L452= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV99671527; called by muse, mutect2, varscan2
- ADCY8 | c.1173C>A p.T391= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV99654010; called by muse, mutect2, varscan2
- AGFG2 | c.549A>G p.A183= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as COSV99499529; called by muse, mutect2, varscan2
- ANKMY1 | c.1230G>A p.E410= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV56033484, COSV99803076; called by muse, mutect2, varscan2
- ANKRD20A1 | c.918A>T p.S306= | Silent (SNP) | VAF 49/273 reads (18%) | called by muse, mutect2, varscan2
- ANKRD30A | c.3789A>G p.L1263= (on ENST00000611781; = p.L1207= on NM_052997.2) | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100654323; called by muse, mutect2
- ANKRD55 | c.1008C>A p.P336= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as rs745463920, COSV100591589; called by muse, mutect2, varscan2
- ARHGEF11 | c.1452G>T p.G484= | Silent (SNP) | VAF 60/197 reads (30%) | catalogued as COSV100810410; called by muse, mutect2, varscan2
- ATP1A2 | c.2346C>A p.P782= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as COSV63402172, COSV63406087; called by muse, mutect2, varscan2
- ATP6V0A4 | c.693C>A p.L231= | Silent (SNP) | VAF 44/238 reads (18%) | catalogued as COSV100023607; called by muse, varscan2
- BPIFB2 | c.171G>A p.L57= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV99401629; called by muse, mutect2, varscan2
- BRI3BP | c.522G>T p.L174= | Silent (SNP) | VAF 30/147 reads (20%) | catalogued as COSV100413156; called by muse, mutect2, varscan2
- C2orf16 | c.3345C>T p.V1115= | Silent (SNP) | VAF 59/190 reads (31%) | catalogued as COSV100820967; called by muse, mutect2, varscan2
- CCDC148 | c.387T>C p.P129= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV99321334; called by muse, mutect2, varscan2
- CDC42BPB | c.4173T>A p.P1391= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV100775582; called by muse, mutect2, varscan2
- CDCP2 | c.498G>T p.P166= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV100313644, COSV61283800; called by muse, mutect2, varscan2
- CFTR | c.379T>C p.L127= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV50058315, COSV99139138; called by muse, mutect2, varscan2
- CHAT | c.1752G>T p.V584= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as COSV100340784; called by muse, mutect2, varscan2
- CHST8 | c.642C>A p.G214= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV99381555; called by muse, mutect2, varscan2
- COCH | c.522C>A p.I174= (on ENST00000216361 / NM_001347720.1; = p.I109= on NM_004086.3) | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as rs1043101984, COSV53553035; called by muse, mutect2, varscan2
- COL10A1 | c.772C>A p.R258= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs765628474, COSV99684430; called by muse, mutect2, varscan2
- COL20A1 | c.3195C>A p.S1065= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100490619; called by muse, mutect2, varscan2
- COL4A4 | c.3432A>G p.P1144= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as rs1343894106, COSV100307573; called by muse, mutect2, varscan2
- CSPG4 | c.4827C>A p.S1609= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV100414110; called by muse, mutect2, varscan2
- DHRS3 | c.358C>T p.L120= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV100879675; called by muse, mutect2, varscan2
- DZIP3 | c.12A>G p.L4= | Silent (SNP) | VAF 21/142 reads (15%) | catalogued as COSV100848030; called by muse, mutect2, varscan2
- EMC8 | c.460A>C p.R154= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV99495790; called by muse, mutect2, varscan2
- ESR1 | c.408C>T p.P136= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV99240871; called by muse, mutect2, varscan2
- FAM171B | c.501C>T p.F167= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV100488947; called by muse, mutect2, varscan2
- FAM171B | c.2127G>T p.V709= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV100488948; called by muse, mutect2, varscan2
- FAT3 | c.11688G>T p.L3896= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV99970342; called by muse, mutect2, varscan2
- GABRR3 | c.1263G>T p.R421= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV101512348; called by muse, mutect2, varscan2
- GPX6 | c.402C>G p.L134= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as COSV100724901; called by muse, mutect2, varscan2
- HSPG2 | c.4875C>T p.S1625= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV101021146; called by muse, mutect2, varscan2
- HTR3A | c.1281A>G p.Q427= | Silent (SNP) | VAF 65/169 reads (38%) | catalogued as COSV100248598; called by muse, mutect2, varscan2
- IBTK | c.1095A>G p.A365= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV100091389; called by muse, mutect2, varscan2
- IGHV4-59 | c.282G>A p.K94= | Silent (SNP) | VAF 72/283 reads (25%) | catalogued as rs781787272; called by muse, mutect2, varscan2
- KCNS1 | c.1005C>A p.G335= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100067463; called by muse, mutect2, varscan2
- LDHAL6B | c.705T>C p.H235= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as rs767853450, COSV99896494; called by muse, mutect2, varscan2
- LEP | c.42C>A p.P14= | Silent (SNP) | VAF 34/199 reads (17%) | catalogued as COSV100451467; called by muse, mutect2, varscan2
- LRRIQ1 | c.3091T>C p.L1031= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV101280693; called by muse, mutect2, varscan2
- LYZL6 | c.148C>T p.L50= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs927776600; called by muse, mutect2, varscan2
- MACF1 | c.138C>T p.N46= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as rs1217950915, COSV100486158; called by muse, mutect2, varscan2
- MAML2 | c.75G>T p.G25= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV101594183, COSV73262659; called by muse, mutect2, varscan2
- MAP2 | c.3051G>A p.K1017= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as rs1303494443, COSV52280006, COSV52295115; called by muse, mutect2, varscan2
- MARCO | c.702G>T p.G234= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs779048147, COSV100503787; called by muse, mutect2, varscan2
- MEMO1 | c.492A>T p.S164= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV54457491, COSV99704628; called by muse, mutect2, varscan2
- MMS22L | c.1608A>G p.L536= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs755065071, COSV99247601; called by muse, mutect2, varscan2
- MUC16 | c.37245C>A p.T12415= | Silent (SNP) | VAF 37/137 reads (27%) | catalogued as COSV101201307, COSV67466841; called by muse, mutect2, varscan2
- MUC21 | c.831A>C p.T277= | Silent (SNP) | VAF 63/331 reads (19%) | catalogued as COSV100888913; called by muse, mutect2, varscan2
- NBPF1 | c.1944G>C p.L648= | Silent (SNP) | VAF 84/856 reads (10%) | catalogued as COSV99844867; called by muse, mutect2
- NCAPD2 | c.2400G>A p.G800= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs115791107; called by muse, mutect2, varscan2
- NFATC2 | c.1095A>G p.P365= | Silent (SNP) | VAF 79/264 reads (30%) | catalogued as COSV101044615; called by muse, mutect2, varscan2
- NRSN2 | c.459C>T p.P153= | Silent (SNP) | VAF 42/135 reads (31%) | catalogued as rs758586867, COSV101206809; called by muse, mutect2, varscan2
- NRXN1 | c.3963T>A p.I1321= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as COSV100640644; called by muse, mutect2, varscan2
- NUP205 | c.1509C>T p.D503= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99607482; called by muse, mutect2, varscan2
- NXPE3 | c.468G>T p.G156= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as COSV99840137; called by muse, mutect2, varscan2
- OR10R2 | c.750A>T p.S250= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV100936835, COSV63769517; called by muse, mutect2, varscan2
- OR4C46 | c.477C>G p.L159= | Silent (SNP) | VAF 50/137 reads (36%) | catalogued as COSV100060946, COSV60218857; called by muse, mutect2, varscan2
- OR4K5 | c.441C>A p.I147= | Silent (SNP) | VAF 72/716 reads (10%) | catalogued as COSV100262591; called by muse, mutect2
- OR56A1 | c.258C>A p.A86= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as COSV100360534; called by muse, mutect2, varscan2
- OR7G2 | c.645C>A p.I215= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as COSV100560566; called by muse, mutect2, varscan2
- OR8B12 | c.111C>T p.T37= | Silent (SNP) | VAF 29/132 reads (22%) | catalogued as rs375814030, COSV100172913, COSV60911893; called by muse, mutect2, varscan2
- OTOF | c.4407C>A p.S1469= (on ENST00000272371 / NM_194248.3; = p.S702= on NM_004802.4) | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as COSV55522636; called by muse, mutect2, varscan2
- PASD1 | c.768T>C p.V256= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as COSV100949565; called by muse, mutect2, varscan2
- PCDH15 | c.1698C>A p.T566= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV57317213; called by muse, mutect2, varscan2
- PCDHGB6 | c.96G>T p.P32= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs778209794, COSV99545705; called by muse, mutect2, varscan2
- PCLO | c.3333C>T p.T1111= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV100436916; called by muse, mutect2, varscan2
- PEAK3 | c.750A>T p.A250= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100457436; called by muse, mutect2, varscan2
- PIK3CB | c.111C>T p.P37= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV100006029; called by muse, mutect2, varscan2
- PITX2 | c.912C>G p.S304= (on ENST00000354925 / NM_001204397.1; = p.S311= on NM_000325.6) | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100146460; called by muse, mutect2
- PLCXD2 | c.327G>T p.G109= | Silent (SNP) | VAF 38/143 reads (27%) | catalogued as rs1264650210, COSV101210139; called by muse, mutect2, varscan2
- PNLIPRP2 | c.1020G>A p.V340= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100077946; called by muse, mutect2, varscan2
- PNPLA8 | c.1413A>T p.P471= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV99993770; called by muse, mutect2, varscan2
- POLM | c.588G>T p.L196= | Silent (SNP) | VAF 48/115 reads (42%) | catalogued as COSV99641983; called by muse, mutect2, varscan2
- PPFIA2 | c.2022A>T p.T674= | Silent (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2
- RNASEL | c.1791G>C p.R597= | Silent (SNP) | VAF 47/158 reads (30%) | catalogued as COSV100842637; called by muse, mutect2, varscan2
- SALL3 | c.2343C>G p.S781= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV101610046; called by muse, mutect2, varscan2
- SCN1A | c.5241C>T p.N1747= (on ENST00000303395 / NM_001202435.3; = p.N1736= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 99/319 reads (31%) | catalogued as COSV100321818; called by muse, mutect2, varscan2
- SDHAF3 | c.30G>C p.R10= | Silent (SNP) | VAF 11/132 reads (8%) | catalogued as rs1367051318, COSV100836528; called by muse, mutect2
- SEC22A | c.438G>A p.K146= | Silent (SNP) | VAF 57/239 reads (24%) | catalogued as COSV100007123; called by muse, mutect2, varscan2
- SEPTIN14 | c.1254T>A p.T418= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV101193421; called by muse, mutect2, varscan2
- SFN | c.441C>T p.A147= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as rs760333868, COSV100212868; called by muse, mutect2, varscan2
- SIGLEC1 | c.642C>A p.I214= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as COSV99170482; called by mutect2, varscan2
- SLC2A14 | c.1509C>A p.G503= | Silent (SNP) | VAF 63/204 reads (31%) | catalogued as COSV100533987; called by muse, mutect2, varscan2
- SLC35F1 | c.741G>T p.V247= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV100838090; called by muse, mutect2, varscan2
- SLC35G3 | c.519G>T p.V173= | Silent (SNP) | VAF 110/246 reads (45%) | catalogued as COSV99269156; called by muse, mutect2, varscan2
- SLC39A10 | c.795G>T p.R265= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV100660751, COSV62767534; called by muse, mutect2, varscan2
- SLC46A2 | c.225C>A p.S75= | Silent (SNP) | VAF 62/164 reads (38%) | catalogued as COSV100953502; called by muse, mutect2, varscan2
- SLC52A2 | c.40C>T p.L14= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs562675049, COSV100096030; called by muse, mutect2, varscan2
- SLC6A2 | c.1695C>G p.S565= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV99574492; called by muse, mutect2, varscan2
- SND1 | c.2268T>G p.P756= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as COSV100691004; called by muse, mutect2, varscan2
- SORCS3 | c.624C>A p.S208= | Silent (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- SYNE1 | c.4353T>C p.F1451= (on ENST00000367255 / NM_182961.4; = p.F1458= on NM_033071.3) | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV99576313; called by muse, mutect2
- TEKT3 | c.366G>T p.V122= | Silent (SNP) | VAF 51/129 reads (40%) | catalogued as COSV100107275; called by muse, mutect2, varscan2
- TEKT4 | c.786C>A p.A262= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99726702; called by muse, mutect2, varscan2
- TF | c.1413G>C p.T471= | Silent (SNP) | VAF 75/322 reads (23%) | catalogued as COSV99396351; called by muse, mutect2, varscan2
- TGM6 | c.57C>A p.A19= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV99172597; called by muse, mutect2, varscan2
- TMEM38A | c.96C>T p.V32= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs1330107970, COSV99495468; called by muse, mutect2, varscan2
- TNN | c.2955G>T p.T985= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as COSV99512834; called by muse, mutect2, varscan2
- TRIM69 | c.384A>T p.P128= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV100274405; called by muse, mutect2, varscan2
- TTN | c.78060T>A p.P26020= (on ENST00000591111; = p.P18596= on NM_003319.4) | Silent (SNP) | VAF 69/255 reads (27%) | catalogued as COSV100627059; called by muse, mutect2, varscan2
- UNC79 | c.6405A>T p.L2135= (on ENST00000393151 / NM_001346218.2; = p.L1958= on NM_020818.5) | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV56377664; called by muse, mutect2
- USP43 | c.1260G>T p.L420= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV99557011; called by muse, mutect2, varscan2
- WNK3 | c.780G>A p.G260= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100672002; called by muse, mutect2, varscan2
- XKR4 | c.835C>A p.R279= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as rs1404145285, COSV100533831, COSV59299905, COSV59312309; called by muse, mutect2, varscan2
- ZEB2 | c.1779C>G p.P593= | Silent (SNP) | VAF 44/144 reads (31%) | catalogued as CD034866, COSV100356751; called by muse, mutect2, varscan2
- ZNF43 | c.2238C>G p.S746= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100731941, COSV100731993; called by muse, mutect2, varscan2
- ZNF80 | c.804T>C p.S268= | Silent (SNP) | VAF 28/145 reads (19%) | catalogued as COSV100352136; called by muse, mutect2, varscan2
- ZNF831 | c.4797G>T p.G1599= | Silent (SNP) | VAF 56/131 reads (43%) | catalogued as COSV100926221; called by muse, mutect2, varscan2
- ACTC1 | c.-1G>T | 5'UTR (SNP) | VAF 71/237 reads (30%) | catalogued as COSV99292100; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848549 C>A | 5'Flank (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851296 G>C | 3'Flank (SNP) | VAF 57/100 reads (57%) | called by muse, mutect2, varscan2
- DCHS2 | n.7584G>T | RNA (SNP) | VAF 18/78 reads (23%) | catalogued as COSV61769190; called by muse, mutect2, varscan2
- DCHS2 | n.6787A>G | RNA (SNP) | VAF 35/90 reads (39%) | catalogued as COSV100602521; called by muse, mutect2, varscan2
- RMDN2 | c.452+21829G>C | Intron (SNP) | VAF 32/121 reads (26%) | catalogued as COSV99308163; called by muse, mutect2, varscan2
- SHANK1 | c.2390-227C>T | Intron (SNP) | VAF 4/11 reads (36%) | catalogued as rs1231430181, COSV53256209, COSV99521882; called by muse, mutect2
- SNORD116-22 | n.53G>T | RNA (SNP) | VAF 56/198 reads (28%) | called by muse, mutect2, varscan2
- VNN3 | c.*478C>G | 3'UTR (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99258656; called by muse, mutect2, varscan2
- XIST | n.7390A>T | RNA (SNP) | VAF 73/111 reads (66%) | called by muse, mutect2, varscan2
